Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TI, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TI-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:

Final 1

Patient Name:

MRN:

Service Date/Time:

DOB/Age/Gender:

Male Provider:

Location: Responsible Staff:

~~C66X~~ ICD-O-3
Astrocytoma, grade III 9401/3
~~path~~ Astrocytoma, fibrillary 9420/3
Site: Brain, supratentorial C71.0
~~path~~ Brain, overlapping lesion C71.8
4/22/14

PATHOLOGICAL DIAGNOSIS:

A. BRAIN, PARIETAL TEMPORAL, MAIN, EXCISIONAL BIOPSIES: FIBRILLARY ASTROCYTOMA, DIFFUSELY INFILTRATING. MIB-1 LABELLING INDEX 2%.
B. BRAIN, PARIETAL TEMPORAL, DEEP, EXCISIONAL BIOPSY: ANAPLASTIC ASTROCYTOMA. MIB-1 LABELLING INDEX 8%.
C. BRAIN, PARIETAL TEMPORAL, DEEP MARGIN, EXCISIONAL BIOPSY: FIBRILLARY ASTROCYTOMA, INFILTRATING.
D. BRAIN, PARIETAL TEMPORAL, EXCISIONAL BIOPSIES: GLIOMA WITH ATYPICAL FEATURES.
SEE MICROSCOPIC AND COMMENT.

Operation/Specimen: Brain, parietal temporal lobe.

Clinical History and Pre-Op Dx: year old man with recent onset seizure, and large diffuse tumor with small focal area of enhancement.
GROSS PATHOLOGY: Three parts.

A. Received fresh, two fragments, 1.3 and 0.9 cm across each. Firm, tannish-white, non-necrotic. In total #1-4.
INTRAOPERATIVE CONSULTATION: Brain, parietal temporal: Glioma, low grade.

B. Received fresh, one fragment, discoid, 0.9 cm across in greatest dimension. Soft, granular, yellowish-red. In total #5.
INTRAOPERATIVE CONSULTATION: Brain, parietotemporal: Intermediate glioma.

C.

SPECIMEN: 3, deep margin permanent.

FIXATIVE: Saline.

GENERAL: A 1.5 x 1.0 x 0.6 cm. soft, red-tan tissue fragment.

SECTIONS: 6, all.

D.

SPECIMEN: 4, permanent tumor.

FIXATIVE: Saline.

GENERAL: A 3.0 x 2.0 x 1.0 cm., 1.9 gm. aggregate of several fragments of red to gray-tan brain tissue.

SECTIONS: 7,8 - all.

MICROSCOPIC: A. Portions of cerebral cortex and adjacent white matter diffusely infiltrated by a glial neoplastic proliferation. The neoplastic cells have moderate nuclear pleomorphism with rounded and elongated shapes. The neuropil is rarefied and contains numerous reactive astrocytes. There are no areas of necrosis, microvascular cellular proliferation, or mitoses.

B. Solid portion of tumor made of cells frequently exhibiting a gemistocytic phenotype, with prominent nuclear pleomorphism, and

[page 2 of 2]
nuclear features of anaplasia. Karyorrhexis is focally prominent, and mitotic figures are rather frequent. The neoplastic nuclei have a tendency for a round outline, and the vasculature is capillary-type with interanastomosing vessels.

C. Portions of gray and white matter with diffuse infiltration by a glial neoplasm with rarefaction of the neuropil. The neoplastic cells are small and irregular with a moderate degree of pleomorphism. Mitoses, microvascular cellular proliferation, and necrosis are absent.

D. Portions of cerebral cortex and white matter diffusely infiltrated by a glial neoplastic proliferation of moderate cellularity and nuclear atypia. The nuclei are round and elongated. Focally, the tumor is more cellular, and the tumor cells are surrounded by perinuclear halos; the background is finely fibrillary and has fine capillary type vessels, minigemistocytes and true gemistocytes. However, areas of necrosis, mitotic figures or necrosis are absent.

SPECIAL STAINS: Immunoperoxidase methods for GFAP and MIB-1 were performed on blocks #1 and 5, and for CD34 (a vascular marker) on block #1. The GFAP brings up the astrocytic nature of the tumor cells. The CD34 highlights the microvasculature. With the MIB-1 labelling indices of 2% in specimen A and 8% in specimen B are determined.

COMMENT: The lesion is a neoplastic proliferation of glial cells that in the superficial specimen (A) has the appearance of an astrocytoma (grade II) with a MIB-1 labelling index of less than 1%. In the deeper specimen (B), the tumor has features of anaplasia (grade III) with a gemistocytic phenotype and a MIB-1 index of 8%. The tumor is present in the deep margin (C). In the fourth specimen (D) the histology is intermediate between A and B, and there is suggestion of an oligodendroglial component.

TISSUE COMMITTEE CODE:

BILLING CODES:

Source: NCI Genomic Data Commons file 77effe80-ed2b-4b10-b154-f81aa12bbe6e (TCGA-DU-A7TI.F365952B-D839-4B07-953A-7EBE3B9A45BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).